Somatic mutation profile of tumor specimen 6c9a5bdc-0f0e-4cc8-aec5-63091c (aliquot 6c9a5bdc-0f0e-4cc8-aec5-63091c_D6) from CPTAC case 02OV044, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 6c9a5bdc-0f0e-4cc8-aec5-63091c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 851ca727-b94a-4159-8af4-5660455b35c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3e46ddab-ce45-439a-8812-43eb90 (Blood Derived Normal), aliquot 3e46ddab-ce45-439a-8812-43eb90_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7614b2b9-35fe-432d-85f0-74933b740ab1

The open-access MAF lists 73 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 19, Intron 4, In Frame Del 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, RNA 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+2T>G p.X224_splice | Splice Site (SNP) | VAF 284/376 reads (76%) | hotspot (GDC flag); catalogued as CS034998, CS0910926, COSV52677962, COSV52797769, COSV53179168; called by muse, varscan2
- ASAP1 | c.2955G>T p.Q985H | Missense Mutation (SNP) | VAF 260/918 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63052171; called by muse, mutect2, varscan2
- IGHE | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 86/707 reads (12%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.491); catalogued as rs1342741232; called by muse, mutect2, varscan2
- ITGA4 | c.2415G>A p.M805I | Missense Mutation (SNP) | VAF 139/263 reads (53%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs764502797, COSV67897449; called by muse, mutect2, varscan2
- ITGA4 | c.2574_2575del p.R859Sfs*25 | Frame Shift Del (DEL) | VAF 43/176 reads (24%) | catalogued as rs755310505; called by mutect2, pindel, varscan2
- KDM1B | c.2164G>A p.V722M (on ENST00000449850; = p.V489M on NM_153042.4) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1561956343, COSV52811227; called by muse, mutect2, varscan2
- NCAPD2 | c.1904C>T p.T635I | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as rs1448390571; called by muse, mutect2, varscan2
- OCA2 | c.1064C>A p.A355E | Missense Mutation (SNP) | VAF 224/532 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62338259; called by muse, mutect2, varscan2
- RAB11FIP2 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 225/288 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1316460402, COSV62925530; called by muse, mutect2, varscan2
- SIPA1L2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 170/577 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs749117335, COSV53385818; called by muse, mutect2, varscan2
- SPATA21 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs1286520944; called by muse, mutect2, varscan2
- WDR54 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs756894142; called by muse, mutect2, varscan2
- BAG3 | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- CDON | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 168/198 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPI | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CFAP54 | c.2497+1G>A p.X833_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- CFLAR | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CROT | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CYTIP | c.1060del p.E354Rfs*40 | Frame Shift Del (DEL) | VAF 160/276 reads (58%) | called by mutect2, pindel*, varscan2
- DCLK2 | c.857G>C p.S286T | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DIAPH1 | c.1115A>T p.D372V | Missense Mutation (SNP) | VAF 117/422 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK11 | c.4183C>A p.L1395I | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- EFL1P1 | n.1235A>C | Splice Region (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2
- FANCD2 | c.2126C>G p.A709G | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, varscan2
- HMGCR | c.2640A>T p.Q880H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.17); called by muse, mutect2
- IL10RB | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IRX3 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCNV1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MAFB | c.358C>G p.P120A | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MC2R | c.494_520del p.M165_P173del | In Frame Del (DEL) | VAF 121/412 reads (29%) | called by mutect2, pindel, varscan2
- MED12 | c.1105A>T p.I369F | Missense Mutation (SNP) | VAF 14/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- MSRB1 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MYLK2 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYOM3 | c.961_1011del p.I321_K337del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- OTOF | c.1414A>G p.S472G | Missense Mutation (SNP) | VAF 138/359 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PCSK4 | c.1085A>T p.H362L | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PRICKLE1 | c.1573T>G p.S525A | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- PRR4 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RALGAPB | c.4291G>A p.G1431S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBPJL | c.595_597del p.K199del | In Frame Del (DEL) | VAF 126/364 reads (35%) | called by pindel, varscan2
- RP1L1 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 294/367 reads (80%) | SIFT tolerated (0.43); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RPGRIP1 | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- STYX | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TMEM30A | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIML1 | c.357C>A p.S119R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2
- TRPM8 | c.2316C>A p.Y772* | Nonsense Mutation (SNP) | VAF 412/657 reads (63%) | called by muse, mutect2, varscan2
- TUFT1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP5PB | c.675A>G p.Q225= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs565196606; called by muse, mutect2, varscan2
- C5orf51 | c.57T>C p.A19= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as rs777269058; called by muse, mutect2, varscan2
- CATSPER1 | c.507C>T p.H169= | Silent (SNP) | VAF 133/350 reads (38%) | catalogued as rs779016319, COSV56408823; called by muse, mutect2, varscan2
- CDC37 | c.286C>A p.R96= | Silent (SNP) | VAF 94/210 reads (45%) | called by muse, mutect2, varscan2
- CDK10 | c.717C>T p.L239= (on ENST00000353379 / NM_052988.5; = p.L168= on NM_052987.4) | Silent (SNP) | VAF 198/264 reads (75%) | called by muse, mutect2, varscan2
- DCST2 | c.1587C>T p.A529= | Silent (SNP) | VAF 106/274 reads (39%) | called by muse, mutect2, varscan2
- GP9 | c.381G>A p.L127= | Silent (SNP) | VAF 151/301 reads (50%) | called by muse, mutect2, varscan2
- HTR7 | c.63G>A p.L21= | Silent (SNP) | VAF 117/287 reads (41%) | called by muse, mutect2, varscan2
- KNTC1 | c.6483T>C p.T2161= | Silent (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- ME3 | c.882C>T p.Y294= | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as COSV60164483; called by muse, mutect2
- RASGRP2 | c.1059A>G p.P353= | Silent (SNP) | VAF 148/386 reads (38%) | catalogued as COSV62450064; called by muse, mutect2, varscan2
- RLN3 | c.150C>G p.S50= | Silent (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
- SALL4 | c.2991C>A p.T997= | Silent (SNP) | VAF 362/546 reads (66%) | called by muse, mutect2, varscan2
- SALL4 | c.1443C>A p.T481= | Silent (SNP) | VAF 440/731 reads (60%) | catalogued as COSV99409700; called by muse, mutect2, varscan2
- SIPA1L2 | c.594C>T p.I198= | Silent (SNP) | VAF 184/565 reads (33%) | catalogued as rs368097996; called by muse, mutect2, varscan2
- SLC12A9 | c.372C>T p.F124= | Silent (SNP) | VAF 76/160 reads (48%) | called by muse, mutect2, varscan2
- SLCO1B3 | c.1824A>T p.G608= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- TEKT1 | c.453C>G p.T151= | Silent (SNP) | VAF 115/136 reads (85%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.367C>T p.L123= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, varscan2
- ABCA3 | c.2700+55C>T | Intron (SNP) | VAF 102/136 reads (75%) | catalogued as rs572920695; called by muse, mutect2, varscan2
- COMMD4 | c.75+84G>C | Intron (SNP) | VAF 128/306 reads (42%) | called by muse, mutect2, varscan2
- ESPNP | n.291C>G | RNA (SNP) | VAF 164/466 reads (35%) | called by muse, mutect2, varscan2
- NCF1B | n.159-1491G>A | Intron (SNP) | VAF 247/800 reads (31%) | catalogued as rs201604882; called by muse, mutect2, varscan2
- NMT2 | c.110+13466G>T | Intron (SNP) | VAF 145/362 reads (40%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791491 G>A | 3'Flank (SNP) | VAF 112/269 reads (42%) | called by muse, mutect2, varscan2
